Gene-level copy-number profile of tumor specimen TCGA-DD-A39V-01A from TCGA case TCGA-DD-A39V, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 77.4 years (28,254 days).
Specimen TCGA-DD-A39V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.5bd3bb77-92be-4ec3-b8e0-b3778429cb66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A39V-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c650921a-24c6-48be-bb02-4381914fb4f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,812; copy number 2: 42,627; copy number 3: 10,301; copy number 4: 2,604; copy number 5: 230; copy number 6: 1,246.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A39V-01A-11D-A20V-01): tumor purity 0.7, ploidy 2.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,476 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:50,762,460–145,066,685, 1,460 genes, copy number 5–6 (broad region; genes not listed).
- chr20:63,981,132–64,313,132, 16 genes, copy number 5 (within-gene range 3–5): PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 1,921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
